Surgical pathology report (de-identified scan), TCGA case TCGA-91-8499, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-8499-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Left video assisted thorascopic lower lobectomy.

Specimen Received:

- A: L12 lymph node
- B: L11 lymph node
- C: L7 lymph node
- D: L8 lymph node
- E: Left lower lobe

=====

=====

EGFR Mutation Analysis

Body site: LLL

RESULTS: Mutations in the EGFR gene were NOT detected. (Wild type/Normal EGFR)

INTERPRETATION: Mutations in exons 18-21 of the EGFR gene were not identified in the provided specimen; however, up to 20% of patients without EGFR mutations respond to tyrosine kinase inhibitor (TKI) therapy.

Final Pathologic Diagnosis:

CAP Protocol Synoptic Report:

Lung, left lower lobe, lobectomy: Poorly differentiated adenocarcinoma,
see NOTE

Specimen: Left lower lobe

Procedure: Lobectomy

Specimen laterality: Left

Tumor site: Left lower lobe

Specimen integrity: Single intact specimen

Tumor size: 2.7 cm and 1.0 cm (greatest dimension)

Tumor focality: Separate tumor nodules in same lobe

Tumor histologic type: poorly differentiated adenocarcinoma

Tumor grade: high grade

Visceral pleura invasion: not identified.

Tumor extension: not applicable.

Margins:

Bronchial margin: Uninvolved by invasive carcinoma

Vascular margin: Uninvolved by invasive carcinoma

Parenchymal margin: Uninvolved by invasive carcinoma

Parietal pleural margin: Not applicable

Chest wall margin: Not applicable

[page 2 of 3]
Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 5 mm

Specify margin: parenchymal

Treatment effect: Not applicable

Lymph-vascular invasion: present

Pathologic Staging (pTNM):

TNM Descriptors: m (multiple primary tumors)

Primary tumor: pT1b

Regional lymph nodes: pN0

Number examined: 15

Number involved: 0

Distant metastasis: Not applicable

Additional pathologic findings: Emphysematous change

A. Lymph nodes, L12, excision:

Four benign lymph nodes (0/4).

B. Lymph nodes, L11, excision:

Three benign lymph nodes (0/3).

C. Lymph node, L7, biopsy:

One benign lymph node (0/1).

D. Lymph node, L8, biopsy:

One benign lymph node (0/1).

E. Lung, left lower lobe, lobectomy:

Poorly differentiated adenocarcinoma.

See Synoptic Report above.

Frozen section diagnoses are confirmed.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:

The tumor cells do not express synaptophysin, chromogranin or p63.

Intraoperative Consult Diagnosis:

E1: Bronchial margin:

Negative for tumor

E2: Lungmass

Poorly differentiated adenocarcinoma

Gross Description:

A. Received in formalin, labeled "L12 lymph node" are four

tan-black, irregular soft tissues ranging from 0.6 x 0.4 x 0.2 cm to 1.3 x 1.0 x

[page 3 of 3]
0.3 cm.

The specimens are entirely submitted as follows:

- 1 three smaller specimens;
- 2 largest specimen bisected.

B. Received in formalin, labeled "L11 lymph node" are three tan-gray, irregular soft tissues ranging from 0.4 x 0.3 x 0.2 cm to 0.8 x 0.6 x 0.2 cm, submitted in toto in one cassette.

C. Received in formalin, labeled "L7 lymph node" is a 1.2 x 0.9 x 0.4 cm tan-gray, irregular soft tissue, bisected and entirely submitted in one cassette.

D. Received in formalin, labeled "L8 lymph node" is a 0.6 x 0.4 x 0.2 cm tan-gray irregular soft tissue, submitted in toto in one cassette.

E. Received fresh, labeled "left lower lobe" is a 21 x 10 x 4 cm lower lobe of lung with 0.8 cm of exposed bronchus. The pleura is purple-pink, smooth to focally indurated, with focal staple lines extending from the hilum. The staple lines are removed and the underlying tissue inked. Sectioning reveals a 2.7 x 2.5 x 2.4 cm tan, firm, heterogeneous, well delineated mass that comes within 0.1 cm from the pleura, 0.8 cm from the nearest stapled margin and 1.5 cm from the bronchial margin. Located 1.5 cm from this mass is a 1.0 x 0.8 x 0.8 cm tan-white, firm, homogeneous, well delineated endobronchial mass which abuts the inked stapled margin, coming within 2.5 cm of the bronchial margin. The uninvolved parenchyma is red-pink, soft and homogeneous. Multiple tan-black, anthracotic hilar lymph nodes are identified up to 0.9 cm. The bronchial margin is taken en face and submitted for frozen section microscopy, now in cassette E1. A section of the mass is submitted for frozen section microscopy, now in cassette E2.

Representative sections of the remaining tissue are submitted as follows:

- 3 vascular margins taken en face;
- 4 larger mass to pleura and inked stapled margin;
- 5 larger mass to pleura;
- 6 random larger mass;
- 7-8 smaller mass in its entirety to inked stapled margin;
- 9 uninvolved parenchyma;
- 10 multiple whole lymph nodes.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: [REDACTED]

Source: NCI Genomic Data Commons file bc5af179-ef8a-4ece-a6d6-564447cc7eda (TCGA-91-8499.99AB423D-DB99-4EF1-BF1F-A8DDDB94E788.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).